Somatic mutation profile of tumor specimen TCGA-HT-7616-01A (aliquot TCGA-HT-7616-01A-11D-2253-08) from TCGA case TCGA-HT-7616, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 75.8 years (27,685 days).
Specimen TCGA-HT-7616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d26cf6c-86e4-49a5-914d-ef5a3a7be7f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7616-10A (Blood Derived Normal), aliquot TCGA-HT-7616-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3139750a-9f60-42e2-ac2d-fe5f1696fc3c

The open-access MAF lists 43 somatic variants for this specimen: 36 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 59/145 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHNAK2 | c.11983G>A p.A3995T | Missense Mutation (SNP) | VAF 131/349 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.129); catalogued as rs369971630; called by muse, mutect2, varscan2
- ARID1B | c.2177del p.P726Lfs*6 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | catalogued as COSV51673025; called by mutect2, pindel, varscan2
- CIC | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV50569481; called by muse, mutect2
- CMYA5 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV71405827; called by muse, mutect2, varscan2
- COG5 | c.2232+1G>A p.X744_splice (on ENST00000347053 / NM_001379512.1; = p.X765_splice on NM_006348.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 33/106 reads (31%) | catalogued as COSV51750633; called by muse, mutect2, varscan2
- DRC7 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.286); catalogued as COSV61054600, COSV61057928; called by muse, mutect2, varscan2
- F13A1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs376147795, CM146351; called by muse, mutect2, varscan2
- FCRL5 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV62514467; called by muse, mutect2, varscan2
- FNDC1 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51937664; called by muse, mutect2, varscan2
- MX2 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 33/127 reads (26%) | catalogued as COSV58096492; called by muse, mutect2, varscan2
- MXRA5 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs745871213, COSV54224205; called by muse, mutect2, varscan2
- OR4A47 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV71444870, COSV71444939; called by muse, mutect2
- PAFAH2 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV65339483; called by muse, mutect2, varscan2
- PPFIA3 | c.2990A>G p.K997R | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1336409574, COSV53256171; called by muse, mutect2, varscan2
- RB1CC1 | c.2830C>G p.Q944E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV50248684; called by muse, mutect2, varscan2
- RS1 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV66106463; called by muse, mutect2, varscan2
- RSPO4 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV54081726; called by muse, mutect2
- RYR2 | c.2517G>T p.E839D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV63685018; called by muse, mutect2, varscan2
- SF3B6 | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV51980806; called by muse, mutect2, varscan2
- SHPRH | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 68/229 reads (30%) | catalogued as COSV51609652; called by muse, mutect2, varscan2
- SLC44A3 | c.862G>A p.A288T (on ENST00000271227 / NM_001114106.3; = p.A240T on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54730098; called by muse, mutect2, varscan2
- SLC5A8 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs747375853, COSV73310648; called by muse, mutect2, varscan2
- SLC7A9 | c.1022T>A p.L341H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50085232; called by muse, mutect2, varscan2
- SOAT1 | c.1128T>G p.I376M | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62654127; called by muse, mutect2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by mutect2, varscan2
- STMN3 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs370557606; called by muse, mutect2, varscan2
- STX11 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV62448656; called by muse, mutect2, varscan2
- TMEM19 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 8/251 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs1489543659, COSV56999893; called by muse, mutect2
- TRIM54 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 126/338 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs988891315, COSV56079683; called by muse, varscan2
- TTN | c.19227G>C p.Q6409H (on ENST00000591111; = p.Q5482H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | PolyPhen possibly damaging (0.66); catalogued as COSV60052594; called by muse, mutect2, varscan2
- ZC3H14 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); catalogued as rs1432669281, COSV51769455; called by muse, mutect2, varscan2
- APPBP2 | c.357del p.I120Ffs*7 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- ASB6 | c.412_413del p.S138* | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by pindel, varscan2
- FUBP1 | c.413dup p.D139* | Frame Shift Ins (INS) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- SLCO3A1 | c.1115dup p.L372Ffs*10 | Frame Shift Ins (INS) | VAF 40/353 reads (11%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.84C>G p.L28= | Silent (SNP) | VAF 54/72 reads (75%) | catalogued as COSV66061601, COSV66065609; called by muse, mutect2, varscan2
- ATRAID | c.465G>A p.L155= (on ENST00000611786; = p.L42= on NM_016085.5) | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as COSV53026706; called by muse, mutect2, varscan2
- KCND2 | c.168G>A p.Q56= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as COSV100477944, COSV58579600; called by muse, mutect2
- LYST | c.5409C>A p.G1803= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1373417685, COSV101088918; called by muse, varscan2
- RET | c.3060G>A p.A1020= | Silent (SNP) | VAF 212/495 reads (43%) | catalogued as rs767152839, COSV60694057; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.55893G>A p.P18631= (on ENST00000591111; = p.P11207= on NM_003319.4) | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as rs727504529, COSV60052534; ClinVar: likely benign; called by muse, mutect2, varscan2
- HERC2P3 | n.1762A>G | RNA (SNP) | VAF 65/271 reads (24%) | called by muse, mutect2, varscan2
